TARGET case TARGET-30-PAVDGG — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c8390b9-380e-5d5b-90ac-f46cd8ef963f

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 181 days.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C38.2; Tissue or organ of origin: Posterior mediastinum; Classification of tumor: primary; Age at diagnosis: 1.8 years (661 days); Year of diagnosis: 2012; Days to last follow up: 181 days; Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ACCL0934.

Follow-up (1 entry)
- Days to follow up: 181 days; Days to first event: 181 days; First event: Death; Year of follow up: 2013.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAVDGG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PAVDGG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 181
- Protocol: ANBL00B1, ACCL0934
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.5
- Histology: Unfavorable
